Somatic mutation profile of tumor specimen MMRF_1496_3_BM_CD138pos (aliquot MMRF_1496_3_BM_CD138pos_T1_KBS5U_L06502) from MMRF case MMRF_1496, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.9 years (14,564 days).
Specimen MMRF_1496_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e67c77-ec80-409c-a690-f98e095b914e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1496_3_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1496_3_PB_CD3pos_C5_KBS5U_L06506; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17229a24-3958-49a1-9e7a-985e2136ba39

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3, Missense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPG | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MXD4 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by mutect2, varscan2
- DDX21 | c.*903A>G | 3'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, varscan2
- DPP10 | c.*1406C>T | 3'UTR (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- ZFP91 | c.*1405_*1410del | 3'UTR (DEL) | VAF 17/51 reads (33%) | called by mutect2, varscan2
- ZNF135 | chr19:58059271 C>G | 5'Flank (SNP) | VAF 36/70 reads (51%) | catalogued as rs752159324; called by muse, varscan2
